Somatic mutation profile of tumor specimen MP2PRT-PAUMAX-TMP1-A (aliquot MP2PRT-PAUMAX-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUMAX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.2 years (1,158 days).
Specimen MP2PRT-PAUMAX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 787e42a1-ca3b-4c9a-b2c5-828958ff5ef7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMAX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMAX-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e96480b8-2182-4732-8c9c-253623c047c5

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP27A1 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 112/378 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs144701596, CM136627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.15025G>A p.V5009M | Missense Mutation (SNP) | VAF 219/607 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NOM1 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 110/412 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SLC25A39 | c.702G>T p.W234C (on ENST00000377095 / NM_001143780.3; = p.W226C on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/321 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM141 | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 181/600 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 201/587 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- BLOC1S3 | c.9C>T p.S3= | Silent (SNP) | VAF 178/524 reads (34%) | catalogued as COSV99135393; called by muse, mutect2, varscan2
